Somatic mutation profile of tumor specimen TCGA-CV-A468-01A (aliquot TCGA-CV-A468-01A-11D-A25Y-08) from TCGA case TCGA-CV-A468, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 42.1 years (15,372 days).
Specimen TCGA-CV-A468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb3cf304-95ff-46b8-a2fe-aa3ea3d78dcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A468-10A (Blood Derived Normal), aliquot TCGA-CV-A468-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/456b43c6-f28a-47b6-8246-324c2a15fea0

The open-access MAF lists 424 somatic variants for this specimen: 283 protein-altering or splice-affecting, 133 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 133, Nonsense Mutation 18, Splice Site 5, 5'Flank 4, Intron 2, RNA 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555911573, COSV54326740, COSV54346809; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs932293502, COSV55292927; called by muse, mutect2
- ABCA10 | c.3574G>A p.E1192K | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99288741; called by muse, mutect2
- ABCA4 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100933146; called by muse, mutect2
- ACADSB | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100715216; called by muse, mutect2
- ACTL7B | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101012544; called by muse, mutect2
- ADAMTS3 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV99711276; called by muse, mutect2
- ADGRA3 | c.2131G>T p.G711* | Nonsense Mutation (SNP) | VAF 21/247 reads (9%) | catalogued as COSV99293868; called by muse, mutect2
- ADGRB3 | c.4039C>T p.P1347S | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99485486, COSV99486337; called by muse, mutect2
- AHNAK2 | c.10267C>T p.P3423S | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV100317817; called by muse, mutect2
- AHSG | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758967731, COSV99890097, COSV99890236; called by muse, mutect2
- AL136295.1 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs754020328, COSV99938096; called by muse, mutect2, varscan2
- ALDOB | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as rs867022678, COSV66397306; called by muse, mutect2
- APOB | c.4525C>T p.P1509S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV51945572; called by muse, mutect2
- ARFGAP3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs908449549, COSV54312239; called by muse, mutect2
- ARFGEF2 | c.3824C>T p.S1275L | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV64214992; called by muse, mutect2
- ARHGAP17 | c.2411G>A p.R804K (on ENST00000289968 / NM_001006634.3; = p.R726K on NM_018054.6) | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); catalogued as rs1166264475, COSV99253574; called by muse, mutect2
- ARHGEF17 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV99735836; called by muse, mutect2
- ARHGEF40 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV100070423; called by muse, mutect2
- ATP2B3 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as rs782263430, COSV99684743; called by muse, mutect2
- ATP7A | c.3154G>A p.G1052R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782781031; called by muse, mutect2
- ATP7A | c.3155G>A p.G1052E | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430994, COSV58455059; called by muse, mutect2
- ATRX | c.2666C>T p.S889F | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV100970903; called by muse, mutect2
- BARHL1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99707610; called by muse, mutect2
- BCORL1 | c.3653C>T p.P1218L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499816; called by muse, mutect2
- BEND2 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV66215949; called by muse, mutect2, varscan2
- BMP8A | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.263); catalogued as COSV100090153; called by muse, mutect2
- BNC2 | c.2551C>T p.H851Y | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101033485; called by muse, mutect2
- BRINP3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs868141889, COSV66540515; called by muse, mutect2
- C4BPA | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.078); catalogued as COSV100891225; called by muse, mutect2
- C8orf76 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99415068; called by muse, mutect2
- CADPS | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 31/508 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV99338789; called by muse, mutect2
- CAPN5 | c.1588G>A p.D530N (on ENST00000456580; = p.D490N on NM_004055.5) | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV99582251; called by muse, mutect2
- CAPRIN2 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV51836135, COSV99195524; called by muse, mutect2
- CASP8 | c.1180C>T p.P394S (on ENST00000432109 / NM_033355.3; = p.P411S on NM_001228.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51846807, COSV99630233; called by muse, mutect2
- CCDC39 | c.144T>A p.Y48* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | catalogued as COSV99869291; called by muse, mutect2
- CDC42BPA | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62003520; called by muse, mutect2
- CDH10 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.739); catalogued as COSV100051840, COSV52573615; called by muse, mutect2
- CDH9 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs943355232, COSV50444912, COSV99151300; called by muse, mutect2, varscan2
- CDHR2 | c.3537G>A p.K1179= | Splice Region (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99991719; called by muse, mutect2
- CENPE | c.7900C>T p.P2634S | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99478176; called by muse, mutect2, varscan2
- CENPT | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV54650304, COSV54650752, COSV99535160; called by mutect2, varscan2
- CFAP100 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs1157982358, COSV61504574; called by muse, mutect2, varscan2
- CFAP47 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.248); catalogued as COSV99935201; called by muse, mutect2
- CLCN4 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV101073867; called by muse, mutect2
- CNTNAP4 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100271822; called by muse, mutect2
- COL11A2 | c.3604G>A p.G1202S (on ENST00000341947 / NM_080680.3; = p.G1095S on NM_080679.2) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.516); catalogued as rs1562324356, COSV100554144; called by muse, mutect2
- COL15A1 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100897793; called by muse, mutect2
- COL1A2 | c.3199C>T p.R1067C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as rs1186920009, COSV51959082, COSV51969377; called by muse, mutect2
- COL4A1 | c.3269C>A p.P1090Q | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65430641; called by muse, mutect2
- CPNE4 | c.628T>A p.F210I | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV101456735; called by muse, mutect2
- CRX | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as COSV55758399; called by muse, mutect2
- CTNNA2 | c.931A>C p.I311L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100784723; called by muse, mutect2
- CTTN | c.1601G>C p.C534S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100097824; called by muse, mutect2
- CYP2C9 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 11/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53249359; called by muse, mutect2
- DARS1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | catalogued as COSV99927613; called by muse, mutect2
- DCN | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99272341; called by muse, mutect2
- DCSTAMP | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 7/151 reads (5%) | catalogued as COSV52579302, COSV99885930; called by muse, mutect2
- DCTN1 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 25/520 reads (5%) | catalogued as COSV100720971; called by muse, mutect2
- DGCR8 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100708007; called by muse, mutect2
- DNAH1 | c.5758C>T p.H1920Y | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV101326104; called by muse, mutect2
- DNAH5 | c.13468G>A p.G4490R | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866681308, COSV54212973; called by muse, mutect2
- DNAJC21 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.044); catalogued as rs1208669621, COSV57761174; called by muse, mutect2, varscan2
- DOCK2 | c.4733C>T p.P1578L | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV56975168, COSV99913040; called by muse, mutect2
- DOP1A | c.4057G>A p.G1353R | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs771596220, COSV99382150; called by muse, mutect2
- DOP1A | c.4058G>A p.G1353E | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV99382153; called by muse, mutect2
- DPYSL2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60782051; called by muse, mutect2
- EEF1D | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs1232236938, COSV99434951; called by muse, mutect2
- EFCAB12 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV58175058; called by muse, mutect2
- EGFLAM | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100471882; called by muse, mutect2
- EIF3L | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101094567; called by muse, mutect2
- EPCAM | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.809); catalogued as rs864622286, COSV99763989; ClinVar: uncertain significance; called by muse, mutect2
- EPHA7 | c.203T>A p.I68K | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100992406; called by muse, mutect2
- ERC2 | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55662232, COSV99885734; called by muse, mutect2
- FAM135B | c.3506G>A p.G1169E | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52712378; called by muse, mutect2
- FAM135B | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52722973, COSV52735221; called by muse, mutect2
- FAM177B | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62601131; called by muse, mutect2
- FAT2 | c.9562C>T p.R3188C | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55826239; called by muse, mutect2
- FCRL3 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV100943312; called by muse, mutect2
- FILIP1 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385099; called by muse, mutect2
- FLG | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 17/439 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100911401; called by muse, mutect2
- FRAS1 | c.10403C>T p.A3468V | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99352871; called by muse, mutect2
- FREM1 | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV101084774; called by muse, mutect2, varscan2
- FRMPD4 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101043141; called by muse, mutect2
- FRRS1L | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101643920; called by muse, mutect2
- FRYL | c.8237C>T p.S2746F | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.961); catalogued as rs780732528, COSV99977143; called by muse, mutect2, varscan2
- FSCB | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV61217007, COSV61219528; called by muse, mutect2
- FSTL5 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100056575; called by muse, mutect2
- FSTL5 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs866600591, COSV60231443, COSV60239031; called by muse, mutect2, varscan2
- FYB1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100685613; called by muse, mutect2, varscan2
- GABBR2 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 5/82 reads (6%) | catalogued as COSV99410362; called by muse, mutect2
- GABRQ | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100941311; called by muse, mutect2
- GALNT16 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs879027991, COSV100545983; called by muse, mutect2
- GMPS | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99903205; called by muse, mutect2
- GRIA2 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52381024, COSV99644717; called by muse, mutect2, varscan2
- GRIK2 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024416; called by muse, mutect2
- HCN1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV100300656; called by muse, mutect2
- HEATR1 | c.5791G>A p.D1931N | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs747790372, COSV100857666; called by muse, mutect2
- HEATR5A | c.5909C>T p.T1970I | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.361); catalogued as COSV101120099; called by muse, mutect2, varscan2
- HERC2 | c.12730C>T p.Q4244* | Nonsense Mutation (SNP) | VAF 12/279 reads (4%) | catalogued as COSV99874424; called by muse, mutect2
- HSD17B2 | c.239T>A p.V80E | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99556655; called by muse, mutect2
- HUWE1 | c.12923T>G p.L4308R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99472732; called by muse, mutect2, varscan2
- ICA1 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV99655412; called by muse, mutect2
- IL11RA | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1208958651, COSV52405846; called by muse, mutect2
- IL7R | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs201790771, COSV100286322; called by muse, mutect2, varscan2
- INTS10 | c.2126T>A p.L709Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101208698; called by muse, mutect2
- IQUB | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776116828, COSV100227161; called by muse, mutect2
- IRS4 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as COSV64534836; called by muse, mutect2
- ITGA10 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV100994939; called by muse, mutect2
- ITGAX | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51641485; called by muse, mutect2
- KANSL1 | c.2675T>C p.V892A (on ENST00000574590 / NM_001193465.2; = p.V893A on NM_015443.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV52276049; called by muse, mutect2
- KLB | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs777511395, COSV57300382; called by muse, mutect2, varscan2
- KLHL38 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as rs779299751, COSV100384429; called by muse, mutect2, varscan2
- LEPR | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100756595, COSV60762309; called by muse, mutect2
- LRP2 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.257); catalogued as COSV99788868; called by muse, mutect2
- LRRC14 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV52883317; called by muse, mutect2, varscan2
- LRRC36 | c.1807-1G>A p.X603_splice | Splice Site (SNP) | VAF 7/117 reads (6%) | catalogued as COSV99338787; called by muse, mutect2
- LRRIQ1 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 25/484 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV101280554, COSV67830693; called by muse, mutect2
- LRRN3 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV57823792; called by muse, mutect2
- LTBR | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as COSV99965309; called by muse, mutect2
- MACROD2 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99434709; called by muse, mutect2, varscan2
- MAP3K19 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100208694; called by muse, mutect2
- MARK1 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100857068; called by muse, mutect2
- MCMDC2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV100552023; called by muse, mutect2
- MDC1 | c.4319C>T p.S1440F | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100902862; called by muse, mutect2
- MEF2C | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100425467; called by muse, mutect2
- MFAP1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs1209026918; called by muse, mutect2
- MIGA1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.138); catalogued as COSV100889784; called by muse, mutect2
- MINAR1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1484357580, COSV59581814; called by muse, mutect2
- MIOS | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs1390520787, COSV100402811; called by muse, mutect2
- MMRN1 | c.2093G>A p.R698K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99307250; called by muse, mutect2
- MORC2 | c.1904C>T p.P635L (on ENST00000397641 / NM_001303256.3; = p.P573L on NM_014941.3) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99309991, COSV99310602; called by muse, mutect2
- MORN5 | c.172T>A p.W58R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101055855; called by muse, mutect2
- MPRIP | c.2224C>T p.L742F | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505846; called by muse, mutect2
- MUC16 | c.14317G>A p.V4773I | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV101200142; called by muse, mutect2
- MUC16 | c.8132G>A p.G2711E | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV101200144; called by muse, mutect2
- MUC17 | c.5540C>T p.S1847L | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs1315933138, COSV60302122; called by muse, mutect2
- MYCL | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100862348; called by muse, mutect2
- MYH15 | c.584+2T>C p.X195_splice | Splice Site (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99843457; called by muse, mutect2
- MYO9A | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100613702; called by muse, mutect2
- MYOCD | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs751148214, COSV58497739; called by muse, mutect2
- NCDN | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100357432; called by muse, mutect2
- NIT2 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV101237099, COSV67630699; called by muse, mutect2
- OBSCN | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as COSV52772933; called by muse, mutect2
- OMD | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100979056; called by muse, mutect2
- OR13F1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.313); catalogued as COSV100594788; called by muse, mutect2
- OR14J1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147619517; called by muse, mutect2
- OR2T1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs140525966; called by muse, mutect2
- OR2T4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.181); catalogued as COSV63543941; called by muse, mutect2
- OR4K1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs868103485, COSV53462356; called by muse, mutect2
- OR51B6 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100971423; called by muse, mutect2
- OR51I2 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100413410, COSV58298249; called by muse, mutect2
- OR5A1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100118380; called by muse, mutect2
- OR5I1 | c.126A>G p.I42M | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100041470; called by muse, mutect2
- OR5M8 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV59116865; called by muse, mutect2
- OR5W2 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60616359; called by muse, mutect2
- OR6C70 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1414447285, COSV100524425; called by muse, mutect2
- OR6C74 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as COSV59606230, COSV59606882; called by muse, mutect2
- PALM2AKAP2 | c.661G>A p.E221K (on ENST00000259318 / NM_001136562.3; = p.E452K on NM_007203.5) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52177766, COSV52177973; called by muse, mutect2
- PALM2AKAP2 | c.1595C>T p.P532L (on ENST00000259318 / NM_001136562.3; = p.P763L on NM_007203.5) | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV99395325; called by muse, mutect2
- PANX3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043416912, COSV99421551; called by muse, mutect2
- PCDHB1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100128211; called by muse, mutect2
- PCDHGA12 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as rs901310090, COSV52754928; called by muse, mutect2
- PCNX1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); catalogued as rs963548088, COSV99455953; called by muse, mutect2, varscan2
- PCSK2 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.197); catalogued as COSV52743400; called by muse, mutect2, varscan2
- PDE3B | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99962682; called by muse, mutect2
- PER1 | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100424614; called by muse, mutect2
- PKHD1L1 | c.8258C>T p.A2753V | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV101006277; called by muse, mutect2, varscan2
- PLAG1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 21/169 reads (12%) | catalogued as COSV100387966; called by muse, mutect2, varscan2
- PLAG1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as COSV57612530; called by muse, mutect2
- PLEC | c.13907C>T p.A4636V (on ENST00000322810 / NM_201380.4; = p.A4526V on NM_000445.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs781892954, COSV100515222; ClinVar: uncertain significance; called by muse, varscan2
- PLG | c.2271G>A p.Q757= | Splice Region (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100369277; called by muse, mutect2, varscan2
- PLPPR4 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV64566884, COSV64567801; called by muse, mutect2
- PLS1 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100538151; called by muse, mutect2, varscan2
- PLXDC1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59551976, COSV59553619; called by muse, mutect2
- PLXNA2 | c.4018G>T p.V1340L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100885563; called by muse, mutect2
- PNLDC1 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV99277508; called by muse, mutect2
- PNLDC1 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99277509; called by muse, mutect2
- PNMA1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV54100325, COSV99678950; called by muse, mutect2
- PNP | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100828984; called by mutect2, varscan2
- PNPLA8 | c.1621C>G p.L541V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57552699, COSV99993580; called by muse, mutect2
- POMT1 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100586147, COSV100586450; called by muse, mutect2
- POPDC3 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as COSV54643517, COSV99633787; called by muse, mutect2
- PPP4R1 | c.1880C>T p.S627F (on ENST00000400556 / NM_001042388.3; = p.S610F on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99553626; called by muse, mutect2
- PPP4R3A | c.1868A>C p.N623T (on ENST00000554943 / NM_001366432.1; = p.N610T on NM_001284280.1) | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV100466134; called by muse, mutect2, varscan2
- PRAMEF2 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 25/709 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99535343; called by muse, mutect2
- PRB1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 36/666 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV53703345, COSV53703486; called by muse, mutect2
- PREX2 | c.4136T>A p.V1379D | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99907811; called by muse, mutect2, varscan2
- PTPRD | c.5434G>A p.G1812R | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV61971772; called by muse, mutect2, varscan2
- PTPRF | c.237+1G>A p.X79_splice | Splice Site (SNP) | VAF 10/238 reads (4%) | catalogued as COSV100740970; called by muse, mutect2
- PTPRZ1 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101100228; called by muse, mutect2
- PXDN | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99413809; called by muse, mutect2
- PXDNL | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100680397; called by muse, mutect2, varscan2
- RALGAPB | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99484905; called by muse, mutect2
- RASA2 | c.1085T>A p.L362* | Nonsense Mutation (SNP) | VAF 20/304 reads (7%) | catalogued as COSV99656261; called by muse, mutect2
- RECK | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100937520; called by muse, mutect2, varscan2
- RGS22 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.107); catalogued as COSV100693342; called by muse, mutect2, varscan2
- RHOT1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100447332; called by muse, mutect2
- RIMS1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99327565; called by muse, mutect2
- RP1 | c.5113G>A p.D1705N | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs867379082, COSV55126719; called by muse, mutect2, varscan2
- RPGRIP1 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99251186; called by muse, mutect2
- RPL39L | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV56220252, COSV99961551; called by muse, mutect2
- RPTOR | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV100156417; called by muse, mutect2
- RSPO2 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.98); catalogued as COSV99409735; called by muse, mutect2, varscan2
- RXFP2 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1205024505, COSV100034381; called by muse, mutect2
- SCN1B | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV99386608; called by muse, mutect2
- SCN7A | c.4751G>A p.R1584K | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV101313256, COSV69274213; called by muse, mutect2
- SCN7A | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV69272954; called by muse, mutect2
- SCNN1A | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99964782; called by muse, mutect2
- SHCBP1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99077086; called by muse, mutect2
- SLC1A2 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 11/327 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.197); catalogued as COSV53523438; called by muse, mutect2
- SLC38A4 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56966598; called by muse, mutect2
- SLC4A4 | c.1924G>A p.D642N (on ENST00000264485 / NM_001098484.3; = p.D598N on NM_003759.4) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99140428; called by muse, mutect2
- SLC6A1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs867819157, COSV55116263; called by muse, mutect2
- SMG7 | c.1361T>A p.I454K | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100750363; called by muse, mutect2
- SPEF2 | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV100607703; called by muse, mutect2
- SPTA1 | c.1351-1G>A p.X451_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100935000, COSV100935103; called by muse, mutect2
- STAU2 | c.835C>T p.P279S (on ENST00000524300 / NM_001164380.2; = p.P247S on NM_014393.2) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV100869124, COSV100869342; called by muse, mutect2
- STOX1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100057951; called by muse, mutect2
- STOX1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53812597; called by muse, mutect2
- SULT1C3 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61254193; called by muse, mutect2
- SYK | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 23/241 reads (10%) | catalogued as COSV101002501; called by muse, mutect2
- SYNE1 | c.5585G>A p.R1862K (on ENST00000367255 / NM_182961.4; = p.R1869K on NM_033071.3) | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs1175854945; called by muse, mutect2
- SYNJ1 | c.4783C>T p.P1595S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as COSV100449379; called by muse, mutect2, varscan2
- SYNM | c.3731G>A p.G1244E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.273); catalogued as COSV100018865; called by muse, mutect2
- TAF4 | c.2487-1G>A p.X829_splice | Splice Site (SNP) | VAF 6/87 reads (7%) | catalogued as COSV99434400; called by muse, mutect2
- TAF7L | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61256332; called by muse, mutect2, varscan2
- TCEAL6 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376334850, COSV65653903; called by muse, varscan2
- THSD4 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55970682; called by muse, mutect2
- TIGD2 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100392376; called by muse, mutect2
- TJAP1 | c.631G>A p.E211K (on ENST00000372445 / NM_001146016.1; = p.E201K on NM_080604.3) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as COSV99446858; called by muse, mutect2
- TLR4 | c.655C>T p.Q219* (on ENST00000355622 / NM_138554.5; = p.Q179* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 17/171 reads (10%) | catalogued as COSV100790658, COSV62924436; called by muse, mutect2
- TMEM200A | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV99759407; called by muse, mutect2
- TONSL | c.3647G>A p.G1216D | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV52870949, COSV99465684; called by muse, mutect2
- TONSL | c.3646G>A p.G1216S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs200752425, COSV99465688; called by muse, mutect2
- TP53 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV52693704, COSV52845855, COSV99411018; called by muse, mutect2, varscan2
- TRIM23 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99140047; called by muse, mutect2
- TRPC3 | c.1971T>A p.F657L (on ENST00000379645 / NM_001366479.2; = p.F584L on NM_003305.2) | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99312777; called by muse, mutect2
- TTC29 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57273436, COSV57281175; called by muse, mutect2
- TTN | c.23114G>A p.G7705E (on ENST00000591111; = p.G6778E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/214 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV60360516; called by muse, mutect2
- TTN | c.16558G>A p.G5520R (on ENST00000591111; = p.G4593R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/266 reads (7%) | PolyPhen benign (0.058); catalogued as COSV100617121; called by muse, mutect2
- UBXN11 | c.1033G>A p.G345S (on ENST00000374221 / NM_183008.2; = p.G312S on NM_145345.2) | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV99582306; called by muse, mutect2
- UBXN6 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs1305110468, COSV100011862; called by muse, mutect2
- UNC5C | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV101497926; called by muse, mutect2
- UPF1 | c.1805A>G p.D602G (on ENST00000599848 / NM_001297549.2; = p.D591G on NM_002911.4) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99439744; called by muse, mutect2
- URB2 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV99271331; called by muse, mutect2
- USP34 | c.5084T>C p.F1695S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV101277066; called by muse, mutect2
- USP9X | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.122); catalogued as COSV100199438; called by muse, mutect2
- VARS2 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422939; called by muse, mutect2
- XPO7 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV99381441; called by muse, mutect2
- ZCCHC12 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100038538; called by muse, mutect2, varscan2
- ZFP42 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1245898046, COSV58816672; called by muse, mutect2, varscan2
- ZFPM2 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65874110; called by muse, mutect2
- ZNF135 | c.1772C>T p.S591F (on ENST00000313434 / NM_001289401.2; = p.S603F on NM_003436.4) | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100536648; called by muse, mutect2
- ZNF365 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV67925417, COSV67925766; called by muse, mutect2
- ZNF536 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100835325; called by muse, mutect2
- ZNF571 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs1315277277, COSV100143820; called by muse, mutect2
- ZNF701 | c.1246G>A p.G416R (on ENST00000301093; = p.G350R on NM_018260.3) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99990866; called by muse, mutect2
- ZNF701 | c.1247G>A p.G416E (on ENST00000301093; = p.G350E on NM_018260.3) | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99990868; called by muse, mutect2
- ZNF804A | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV56461312; called by muse, mutect2
- ATP10A | c.3840G>A p.M1280I | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- ATP13A1 | c.2494C>A p.P832T | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.27); called by muse, mutect2
- B4GALNT4 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- CC2D1B | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDC25A | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNB3 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP4F3 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- EFHC1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- ETNK2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- GPD2 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- IGHV3-23 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 15/355 reads (4%) | called by muse, mutect2
- KCNS2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LETMD1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- MED27 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MMP24 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- OR51T1 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDHB11 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- REG1A | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 18/435 reads (4%) | called by muse, mutect2
- RELN | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPOUT1 | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2
- TSACC | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.275); called by muse, mutect2
- XPO7 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.285); called by muse, mutect2
- ABCC11 | c.390C>T p.V130= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV100750832; called by muse, mutect2
- ABI3BP | c.2457G>A p.E819= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as COSV99427120; called by muse, mutect2
- ACADL | c.96G>A p.G32= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99284813; called by muse, mutect2
- ACOX3 | c.1623C>T p.S541= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV100711965; called by muse, mutect2
- ADCY8 | c.3423G>A p.K1141= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as COSV99652665; called by muse, mutect2, varscan2
- ADGRE3 | c.1656C>T p.F552= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as rs1284369952, COSV99506292; called by muse, mutect2
- ADGRL1 | c.3357C>T p.I1119= (on ENST00000340736 / NM_001008701.3; = p.I1114= on NM_014921.5) | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV61565736; called by muse, mutect2
- ANKS1B | c.1767C>T p.S589= | Silent (SNP) | VAF 8/280 reads (3%) | catalogued as rs1300869554, COSV61335075; called by muse, mutect2
- APLP1 | c.1737C>T p.S579= (on ENST00000221891 / NM_001024807.3; = p.S578= on NM_005166.4) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99697729; called by muse, mutect2
- ARHGEF10 | c.372C>T p.F124= (on ENST00000398564; = p.F100= on NM_014629.4) | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV50650259; called by muse, mutect2
- ARRDC5 | c.372C>T p.T124= (on ENST00000381781; = p.T110= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- ASPH | c.981G>A p.K327= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV101063965, COSV65245687; called by muse, mutect2, varscan2
- ATP2C2 | c.165G>A p.K55= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1367027152, COSV99298208; called by muse, mutect2
- B3GALT4 | c.993C>T p.S331= | Silent (SNP) | VAF 13/201 reads (6%) | catalogued as COSV101005648; called by muse, mutect2
- BCAS1 | c.1749C>T p.S583= | Silent (SNP) | VAF 12/249 reads (5%) | catalogued as COSV101006256; called by muse, mutect2
- BIRC3 | c.144G>A p.R48= | Silent (SNP) | VAF 6/162 reads (4%) | catalogued as COSV54818617, COSV99679994; called by muse, mutect2
- CCDC8 | c.180G>A p.E60= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100282068; called by muse, mutect2
- CCL25 | c.423C>T p.S141= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV53664248; called by muse, mutect2
- CCT8L2 | c.1560C>T p.I520= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as rs529271182, COSV63461718; called by muse, mutect2
- CD8B | c.648C>T p.T216= (on ENST00000331469 / NM_172213.4; = p.T186= on NM_172102.4) | Silent (SNP) | VAF 25/424 reads (6%) | catalogued as COSV100514560; called by muse, mutect2
- CFAP65 | c.192G>A p.K64= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99838306, COSV99838358; called by muse, mutect2
- CFH | c.2313C>T p.F771= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs994206257, COSV100809429, COSV66411071; called by muse, mutect2
- CHD4 | c.4113C>T p.P1371= (on ENST00000357008 / NM_001363606.2; = p.P1384= on NM_001273.5) | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as COSV100538197; called by muse, mutect2
- COG4 | c.2337C>T p.F779= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV99850952; called by muse, mutect2
- CUBN | c.8778C>T p.G2926= | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- CYP2C9 | c.87C>T p.L29= | Silent (SNP) | VAF 11/240 reads (5%) | catalogued as rs1382315341, COSV53252368; called by muse, mutect2
- CYP2J2 | c.279C>T p.G93= | Silent (SNP) | VAF 8/171 reads (5%) | catalogued as COSV100968049; called by muse, mutect2
- DLG5 | c.5193C>T p.V1731= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV100967557; called by muse, mutect2
- DNAH9 | c.1236G>A p.R412= | Silent (SNP) | VAF 20/207 reads (10%) | catalogued as rs561526949, COSV99306278; called by muse, mutect2
- DOCK2 | c.1221G>A p.V407= | Silent (SNP) | VAF 10/251 reads (4%) | catalogued as COSV56954128, COSV99913037; called by muse, mutect2
- DTX3L | c.1230T>C p.S410= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- DYNC1H1 | c.7503C>T p.S2501= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100795013; called by muse, mutect2
- DZIP3 | c.1407C>T p.L469= | Silent (SNP) | VAF 11/208 reads (5%) | catalogued as COSV100847849; called by muse, mutect2
- EFCAB12 | c.771C>T p.I257= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100394654; called by muse, mutect2, varscan2
- EFCAB12 | c.195G>A p.K65= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100394473, COSV100394657; called by muse, mutect2
- EIF4ENIF1 | c.270C>T p.D90= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100349220; called by muse, mutect2
- FBN2 | c.1383C>A p.I461= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as rs1305126016, COSV99328201; called by muse, mutect2
- FBXO7 | c.1395T>A p.I465= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV99832733; called by muse, mutect2
- FGD2 | c.1269G>A p.R423= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- FLNB | c.1527G>A p.G509= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV99913551; called by muse, mutect2
- FLOT1 | c.265C>T p.L89= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as rs773964976, COSV99458223; called by muse, mutect2
- GALNT16 | c.810G>A p.E270= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100545986; called by muse, mutect2
- GATA2 | c.1107C>T p.V369= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100351355; called by muse, mutect2, varscan2
- GJB4 | c.276C>T p.V92= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1322269853, COSV100258522; called by muse, mutect2
- GKN2 | c.376C>T p.L126= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as COSV100187836; called by muse, mutect2
- GPATCH8 | c.3765C>T p.S1255= | Silent (SNP) | VAF 14/303 reads (5%) | catalogued as COSV59193706; called by muse, mutect2
- GRIA2 | c.1851C>T p.L617= | Silent (SNP) | VAF 21/219 reads (10%) | catalogued as COSV99644720; called by muse, mutect2
- GTF2IRD1 | c.639C>T p.A213= | Silent (SNP) | VAF 9/219 reads (4%) | catalogued as rs1554345361, COSV99734844; called by muse, mutect2
- GTPBP3 | c.645G>A p.E215= | Silent (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- HDAC10 | c.1362G>A p.E454= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV50547260, COSV50561130; called by muse, mutect2, varscan2
- HEATR1 | c.5790G>A p.K1930= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as rs1352395597, COSV100857667; called by muse, mutect2
- HRNR | c.1998G>A p.G666= | Silent (SNP) | VAF 15/304 reads (5%) | catalogued as COSV64262430; called by muse, mutect2
- HTRA3 | c.759G>A p.G253= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs1286021224, COSV100246372; called by muse, mutect2, varscan2
- IKBKE | c.945C>T p.S315= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV100898271; called by muse, mutect2
- INTS9 | c.582C>T p.I194= | Silent (SNP) | VAF 8/234 reads (3%) | called by muse, mutect2
- IRAG1 | c.870G>A p.K290= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101351300, COSV70213244; called by muse, mutect2
- ITGA2 | c.1896C>T p.S632= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99670959; called by muse, mutect2
- ITPR3 | c.7108C>T p.L2370= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100953630; called by muse, mutect2
- KIAA2026 | c.312C>T p.P104= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs773546297, COSV99424205; called by muse, mutect2, varscan2
- KMT2B | c.3267C>T p.F1089= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs766304142, COSV55872752; called by mutect2, varscan2
- LCT | c.3330G>A p.E1110= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV99929654; called by muse, mutect2
- LHX4 | c.1035G>A p.G345= | Silent (SNP) | VAF 15/430 reads (3%) | catalogued as COSV99761630; called by muse, mutect2
- LPP | c.84C>T p.S28= | Silent (SNP) | VAF 32/326 reads (10%) | catalogued as rs1326628112, COSV100447561; called by muse, mutect2
- LRRTM4 | c.414G>A p.L138= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as rs1014112551, COSV101297589; called by muse, mutect2
- LYN | c.828C>T p.T276= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV101319610; called by muse, mutect2
- MAP10 | c.2979G>A p.V993= | Silent (SNP) | VAF 12/218 reads (6%) | catalogued as COSV101406514; called by muse, mutect2
- MAP1B | c.456C>T p.L152= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV99702502; called by muse, mutect2
- MED1 | c.3042G>A p.K1014= | Silent (SNP) | VAF 7/171 reads (4%) | called by muse, mutect2
- MEGF8 | c.1074C>T p.L358= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs998981256; called by muse, mutect2
- MPPED1 | c.168G>A p.Q56= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100501251; called by muse, mutect2
- MRC2 | c.2377C>T p.L793= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- MUC13 | c.502C>T p.L168= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as COSV60700271; called by muse, mutect2
- MYH8 | c.2838G>A p.L946= | Silent (SNP) | VAF 20/460 reads (4%) | catalogued as COSV101238456; called by muse, mutect2
- NCOA5 | c.1590C>T p.S530= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV99275682; called by muse, mutect2
- NMUR1 | c.579C>T p.S193= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100532003; called by muse, mutect2
- OGDHL | c.1233C>T p.F411= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100934370; called by muse, mutect2
- OPALIN | c.425G>A p.*142= | Silent (SNP) | VAF 7/171 reads (4%) | catalogued as rs867308282; called by muse, mutect2
- OR10Z1 | c.81C>T p.L27= | Silent (SNP) | VAF 7/191 reads (4%) | catalogued as COSV63523770, COSV63524947, COSV63526801; called by muse, mutect2
- OR1J4 | c.405C>T p.I135= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as rs1236862560, COSV100534287, COSV61589667; called by muse, mutect2, varscan2
- OR1N2 | c.243C>T p.I81= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as COSV65460639; called by muse, mutect2
- OR2T6 | c.837C>T p.T279= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV63217277; called by muse, mutect2
- OR56A3 | c.117C>T p.F39= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs267603043, COSV61568941; called by muse, mutect2
- OR8G5 | c.753C>T p.F251= | Silent (SNP) | VAF 10/169 reads (6%) | catalogued as COSV100422482; called by muse, mutect2
- OR8K1 | c.645C>T p.F215= | Silent (SNP) | VAF 10/155 reads (6%) | catalogued as COSV99687305; called by muse, mutect2
- OR8K3 | c.163T>C p.L55= | Silent (SNP) | VAF 10/242 reads (4%) | catalogued as COSV100449634, COSV57131138; called by muse, mutect2
- PCDH1 | c.843G>A p.E281= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99746390; called by muse, mutect2
- PCDH11X | c.2019C>T p.F673= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100012299; called by muse, mutect2
- PCDHA9 | c.198G>A p.L66= | Silent (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- PCSK2 | c.1416C>T p.S472= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs547514355, COSV99359376; called by muse, varscan2
- PDS5A | c.3207C>T p.S1069= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV100337454; called by muse, mutect2, varscan2
- PELP1 | c.1224C>T p.S408= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1047893967, COSV99343000; called by muse, mutect2
- PHLDB1 | c.3363G>A p.E1121= | Silent (SNP) | VAF 11/161 reads (7%) | catalogued as COSV100616591; called by muse, mutect2
- PLAG1 | c.54C>T p.V18= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100387968; called by muse, mutect2
- PLCB4 | c.3417C>T p.V1139= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV53796144, COSV99595770; called by muse, mutect2, varscan2
- PLD1 | c.2661C>T p.N887= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV100578284; called by muse, mutect2
- PLEC | c.9318G>A p.K3106= (on ENST00000322810 / NM_201380.4; = p.K2996= on NM_000445.5) | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs983563451, COSV100513252, COSV100515226; called by muse, mutect2, varscan2
- PLXDC1 | c.561C>T p.S187= | Silent (SNP) | VAF 12/205 reads (6%) | catalogued as rs1567763350, COSV100195453; called by muse, mutect2
- PLXNA3 | c.2496G>A p.Q832= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100860026; called by muse, mutect2
- PRMT1 | c.237C>T p.S79= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101212290; called by muse, mutect2
- PRPS1L1 | c.138G>A p.E46= | Silent (SNP) | VAF 24/350 reads (7%) | catalogued as rs13231476, COSV101552940, COSV72649907, COSV72649968; called by muse, mutect2
- PSG3 | c.1224C>T p.S408= | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as rs1252194421, COSV100549034; called by muse, mutect2
- QSOX2 | c.2022C>T p.F674= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV100699781; called by muse, mutect2
- RMI1 | c.978C>T p.V326= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100366305; called by muse, mutect2
- RTL9 | c.2352C>T p.L784= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1453999031, COSV101511705; called by muse, mutect2
- RTN2 | c.811C>T p.L271= | Silent (SNP) | VAF 17/270 reads (6%) | catalogued as COSV99838999; called by muse, mutect2
- SAYSD1 | c.13T>C p.L5= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100010190; called by muse, mutect2
- SEMA6D | c.1191C>T p.P397= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV100317123, COSV60382627; called by muse, mutect2
- SEPTIN14 | c.1293G>A p.K431= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV66426092; called by muse, mutect2
- SERPIND1 | c.96G>A p.G32= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99300232; called by muse, mutect2
- SLC4A5 | c.2286G>A p.K762= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100697738; called by muse, mutect2
- SLC6A19 | c.795G>A p.P265= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as rs201084108, COSV100443520; called by muse, mutect2, varscan2
- SORBS2 | c.1278C>T p.Y426= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV99511318; called by muse, mutect2
- SPATA7 | c.1086A>G p.E362= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as rs1345468430, COSV99248054; ClinVar: likely benign; called by muse, mutect2
- SPEF2 | c.3201C>T p.F1067= | Silent (SNP) | VAF 22/207 reads (11%) | catalogued as COSV100607701; called by muse, mutect2, varscan2
- SPTA1 | c.468G>A p.R156= | Silent (SNP) | VAF 21/320 reads (7%) | catalogued as rs762178562, COSV100935104; called by muse, mutect2
- SVEP1 | c.1332G>A p.P444= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs370267821, COSV57043191; called by muse, mutect2
- SYNE1 | c.5817C>T p.I1939= (on ENST00000367255 / NM_182961.4; = p.I1946= on NM_033071.3) | Silent (SNP) | VAF 10/191 reads (5%) | catalogued as rs1348964584, COSV55098686; called by muse, mutect2
- TANC2 | c.5802C>T p.L1934= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV101267484; called by muse, mutect2
- TAS2R13 | c.411C>T p.T137= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV66831537, COSV66831754; called by muse, mutect2
- TBC1D14 | c.327C>T p.S109= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as COSV101298956, COSV68986689; called by muse, mutect2
- TRPC7 | c.75C>T p.A25= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100725756; called by muse, mutect2
- UBE2D2 | c.93C>T p.F31= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV54080918, COSV99551398; called by muse, mutect2
- UNC5C | c.1956G>A p.L652= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV101497927; called by muse, mutect2, varscan2
- VCP | c.1251G>A p.E417= | Silent (SNP) | VAF 24/297 reads (8%) | catalogued as COSV100734240; called by muse, mutect2
- VCP | c.1146G>A p.Q382= | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as COSV100734241; called by muse, mutect2, varscan2
- VWF | c.4215G>A p.K1405= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV99779314; called by muse, mutect2
- WNT6 | c.240C>T p.F80= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as rs1434017926; called by muse, mutect2
- YIPF1 | c.213G>A p.K71= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV99300959; called by muse, mutect2
- YWHAE | c.408C>T p.A136= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs752894008, COSV99981260; called by muse, mutect2
- ZNF506 | c.126C>T p.F42= | Silent (SNP) | VAF 9/181 reads (5%) | catalogued as COSV101475641; called by muse, mutect2
- ZNF570 | c.447G>A p.E149= | Silent (SNP) | VAF 9/267 reads (3%) | called by muse, mutect2
- ZNF721 | c.624C>T p.P208= (on ENST00000338977; = p.P220= on NM_133474.4) | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- ZNF808 | c.606C>T p.I202= | Silent (SNP) | VAF 18/302 reads (6%) | catalogued as COSV100708012; called by muse, mutect2
- AC092718.9 | chr16:81147473 C>T | 5'Flank (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- AC092718.9 | chr16:81147475 T>A | 5'Flank (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- AL353804.4 | chrX:73826122 C>T | 5'Flank (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- DCHS2 | n.2909A>G | RNA (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- DOCK8 | chr9:214736 C>T | 5'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as rs1377164715, COSV101213674; called by muse, mutect2, varscan2
- RIMS2 | c.1692+216G>A | Intron (SNP) | VAF 13/133 reads (10%) | catalogued as COSV99170297; called by muse, mutect2
- TOMM20 | c.121+740C>T | Intron (SNP) | VAF 8/153 reads (5%) | catalogued as COSV100783975; called by muse, mutect2
- TUBB7P | n.1126G>A | RNA (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
